Gene-level copy-number profile of tumor specimen TCGA-CN-A49C-01A from TCGA case TCGA-CN-A49C, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: GX; Age at diagnosis: 67.1 years (24,495 days).
Specimen TCGA-CN-A49C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.be4b6a14-ca8a-4eb6-9ec6-728ca59c05e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A49C-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ecd5c394-8f5e-4c37-9220-d3ed6a0c4e7c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,462; copy number 2: 50,445; copy number 3: 1,010; copy number 4: 1,800; copy number 6: 1; copy number 7: 6; copy number 8: 13; copy number 9: 34; copy number 10: 41; copy number 11: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A49C-01A-11D-A24C-01): tumor purity 0.82, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,754,620–71,452,868, 65 genes, copy number 8–10 (within-gene range 2–10) (broad region; genes not listed).
- chr11:74,012,718–74,324,705, 8 genes, copy number 6–11 (within-gene range 1–11): C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1.
- chr11:76,444,923–77,474,635, 22 genes, copy number 9 (within-gene range 3–9): EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1.
- chr17:39,671,122–39,864,312, 6 genes, copy number 7 (within-gene range 2–7): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.

Autosomal genes at a single copy (total copy number 1): 4,076. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
